Somatic mutation profile of tumor specimen TCGA-76-6285-01A (aliquot TCGA-76-6285-01A-11D-1696-08) from TCGA case TCGA-76-6285, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.8 years (23,674 days).
Specimen TCGA-76-6285-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2d0c87d-123d-4c14-9d79-ad94e5928e45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6285-10A (Blood Derived Normal), aliquot TCGA-76-6285-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3ab8a16-2459-4e96-9053-943ed49bc494

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 30, Silent 18, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOC2 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs577504737, COSV53199650; called by muse, mutect2, varscan2
- ASIC5 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs766433726, COSV73332874; called by muse, mutect2, varscan2
- BPIFB2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1038105186, COSV50068423; called by muse, mutect2, varscan2
- CD1D | c.986+1G>A p.X329_splice | Splice Site (SNP) | VAF 79/208 reads (38%) | catalogued as rs775899867, COSV63808409; called by muse, mutect2, varscan2
- CHRDL2 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765969607, COSV55224392; called by muse, mutect2, varscan2
- CHRM2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs147228075; called by muse, mutect2, varscan2
- CNTN6 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762861042, COSV63182381; called by muse, mutect2, varscan2
- COPS7B | c.67A>T p.S23C | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV62601478; called by muse, mutect2, varscan2
- EIF3E | c.671A>G p.N224S | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV55204852; called by muse, mutect2, varscan2
- EML5 | c.3399G>A p.W1133* | Nonsense Mutation (SNP) | VAF 37/48 reads (77%) | catalogued as COSV61349695; called by muse, mutect2, varscan2
- FBLN2 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as COSV55488651; called by muse, mutect2, varscan2
- FLG | c.11677G>T p.E3893* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as rs770855196, COSV64245473; called by muse, mutect2, varscan2
- GPR182 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV55626760; called by muse, mutect2, varscan2
- HCAR3 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs745907085, COSV63676640; called by muse, varscan2
- HLA-DOA | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761242552, COSV57715118; called by muse, mutect2, varscan2
- HLTF | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59502504; called by muse, mutect2, varscan2
- HS3ST4 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578031781, COSV58802034; called by muse, mutect2, varscan2
- IL17RA | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as rs138404135; called by muse, mutect2, varscan2
- ITGA2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs148042733; called by muse, mutect2, varscan2
- LTBP4 | c.4009G>C p.V1337L (on ENST00000308370 / NM_001042544.1; = p.V1300L on NM_003573.2) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV52587137; called by muse, mutect2, varscan2
- MIDN | c.1290T>G p.S430R | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV56296187; called by muse, mutect2, varscan2
- MUC6 | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs367909154; called by muse, mutect2, varscan2
- NAV2 | c.2009C>T p.T670I (on ENST00000396087 / NM_001244963.2; = p.T647I on NM_145117.5) | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV62329611; called by muse, mutect2, varscan2
- NR2C1 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV58011481; called by muse, mutect2, varscan2
- NYAP1 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs760779356, COSV55720835; called by muse, mutect2, varscan2
- PHETA2 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV58791274; called by muse, mutect2, varscan2
- PREX1 | c.3412A>G p.R1138G | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV64254847; called by muse, mutect2, varscan2
- SH3BP5L | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV63539648; called by muse, mutect2, varscan2
- SHPK | c.823+1G>A p.X275_splice | Splice Site (SNP) | VAF 8/14 reads (57%) | catalogued as COSV56649935; called by muse, varscan2
- SLC27A6 | c.1839G>T p.M613I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV52485745; called by muse, mutect2, varscan2
- SYNJ2 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 115/159 reads (72%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs202038099, COSV62895517; called by muse, mutect2, varscan2
- TAS2R1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1297277024, COSV66778908, COSV66779124; called by muse, mutect2, varscan2
- TIE1 | c.1184T>A p.L395H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100992183, COSV65250713; called by muse, mutect2, varscan2
- TRH | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs752218511, COSV57014793; called by muse, mutect2, varscan2
- USP51 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT tolerated (0.29); PolyPhen benign (0.262); catalogued as COSV72351842; called by muse, mutect2, varscan2
- ZNF492 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs376885920; called by muse, mutect2, varscan2
- OR8U1 | c.186_189del p.F62Lfs*4 | Frame Shift Del (DEL) | VAF 108/383 reads (28%) | called by pindel, varscan2
- AGPAT4 | c.339G>A p.G113= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV57248808; called by muse, mutect2, varscan2
- C8A | c.411C>T p.D137= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs766644316, COSV63485040; called by muse, mutect2, varscan2
- CD93 | c.1701C>T p.S567= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs546513788, COSV55667437; called by muse, mutect2, varscan2
- CRNKL1 | c.372G>A p.P124= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs774052514, COSV55640190; called by muse, mutect2, varscan2
- CSMD2 | c.4314G>A p.P1438= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as rs750813964, COSV53940388; called by muse, mutect2, varscan2
- HPSE2 | c.1432C>T p.L478= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV65196495; called by muse, mutect2, varscan2
- KRT6B | c.1557T>C p.S519= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV52885395; called by muse, mutect2, varscan2
- KRT72 | c.243C>T p.S81= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99537495; called by muse, varscan2
- MYO5B | c.1782T>C p.D594= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs753253103, COSV53226032; called by mutect2, varscan2
- NOS1 | c.1701C>T p.Y567= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs569838932, COSV57617853; called by muse, mutect2, varscan2
- POF1B | c.1119C>T p.Y373= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as rs1174499325, COSV53137980; called by muse, mutect2, varscan2
- RELN | c.876G>A p.A292= | Silent (SNP) | VAF 58/221 reads (26%) | catalogued as rs757968034, COSV59008270; called by muse, mutect2, varscan2
- SP3 | c.1005T>C p.S335= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as COSV59469694; called by muse, mutect2, varscan2
- SYNJ2 | c.501C>T p.H167= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as rs745847436, COSV62899448; called by muse, mutect2, varscan2
- TBX18 | c.1353G>A p.P451= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as rs774472628, COSV63736776; called by muse, mutect2, varscan2
- TPD52L1 | c.39G>A p.P13= | Silent (SNP) | VAF 45/53 reads (85%) | catalogued as rs368146966; called by muse, mutect2, varscan2
- TYW1 | c.1245G>A p.A415= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as rs764260284, COSV62754610; called by muse, varscan2
- ZNF48 | c.1260G>C p.S420= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs761815392, COSV60783913; called by muse, mutect2, varscan2
